Somatic mutation profile of tumor specimen TCGA-DK-A3IQ-01A (aliquot TCGA-DK-A3IQ-01A-31D-A20D-08) from TCGA case TCGA-DK-A3IQ, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 74.5 years (27,194 days).
Specimen TCGA-DK-A3IQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 770c6e91-edb6-42ad-9e4c-a9b2129483a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-A3IQ-10A (Blood Derived Normal), aliquot TCGA-DK-A3IQ-10A-01D-A20D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/303ed87f-979c-422f-90a8-62de0f31f756

The open-access MAF lists 202 somatic variants for this specimen: 145 protein-altering or splice-affecting, 49 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 123, Silent 49, Nonsense Mutation 12, Splice Site 5, Splice Region 3, Intron 3, 3'UTR 2, RNA 1, Frame Shift Del 1, 5'UTR 1, Frame Shift Ins 1, IGR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LDLR | c.253C>T p.Q85* | Nonsense Mutation (SNP) | VAF 31/180 reads (17%) | catalogued as rs875989893, CM950750; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AARS1 | c.1240C>T p.L414F | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV55746201; called by muse, mutect2, varscan2
- ABCC6 | c.2117C>T p.S706F | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52741482; called by muse, mutect2, varscan2
- ABCG5 | c.1792C>T p.P598S | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as COSV53182319; called by muse, mutect2, varscan2
- ABHD15 | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56194797; called by muse, mutect2, varscan2
- AMBRA1 | c.549C>G p.V183= | Splice Region (SNP) | VAF 17/137 reads (12%) | catalogued as COSV54049011; called by muse, mutect2, varscan2
- AMBRA1 | c.448C>T p.Q150* | Nonsense Mutation (SNP) | VAF 15/77 reads (19%) | catalogued as rs1354023827; called by muse, mutect2, varscan2
- AMIGO3 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.159); catalogued as COSV57537577; called by muse, varscan2
- ARHGEF10L | c.1722C>G p.I574M | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV51428324; called by muse, varscan2
- ARID4A | c.2437G>T p.G813C | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.125); catalogued as COSV62162092; called by muse, mutect2, varscan2
- ATP2A1 | c.2590C>G p.H864D | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV62868564; called by muse, mutect2, varscan2
- ATP2B1 | c.282G>C p.K94N | Missense Mutation (SNP) | VAF 46/334 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1267016867, COSV53804144; called by muse, mutect2, varscan2
- ATP8B2 | c.122G>A p.R41H (on ENST00000672630; = p.R8H on NM_001005855.2) | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.228); catalogued as rs1291502459, COSV59244814; called by muse, mutect2
- BPI | c.1284G>A p.P428= (on ENST00000262865; = p.P424= on NM_001725.3) | Splice Region (SNP) | VAF 9/129 reads (7%) | catalogued as rs768021012, COSV53404026; called by muse, mutect2
- BPTF | c.3469C>A p.Q1157K | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.026); catalogued as COSV58831860; called by muse, mutect2, varscan2
- BTBD11 | c.1841G>A p.R614H (on ENST00000280758 / NM_001018072.2; = p.R151H on NM_001017523.2) | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.963); catalogued as rs757220938, COSV55017607; called by muse, mutect2, varscan2
- BTN3A3 | c.55T>C p.F19L | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1006302093, COSV55072206; called by muse, mutect2
- CALML3 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.52); catalogued as rs200163389, COSV59449147; called by muse, mutect2, varscan2
- CEP152 | c.1384A>G p.M462V | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV57856880; called by muse, mutect2, varscan2
- CEP55 | c.661A>G p.K221E | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as COSV65184524; called by muse, mutect2, varscan2
- CFAP58 | c.2585G>T p.G862V | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63832696, COSV63834484; called by muse, mutect2, varscan2
- CLIP1 | c.1852G>A p.D618N (on ENST00000620786 / NM_001247997.1; = p.D607N on NM_002956.2) | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV56797678; called by muse, mutect2, varscan2
- CMSS1 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1309423923, COSV70435643; called by muse, mutect2, varscan2
- CNKSR2 | c.1895G>A p.R632H | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750208984, COSV54260292; called by muse, mutect2
- COL23A1 | c.602C>T p.T201I | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.127); catalogued as COSV66786456; called by muse, mutect2, varscan2
- COL5A2 | c.3344C>G p.A1115G | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.767); catalogued as rs1327629334, COSV66407289; called by muse, mutect2
- CSMD2 | c.3485G>A p.R1162H | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.382); catalogued as rs201989989; called by muse, mutect2, varscan2
- CSMD3 | c.6563C>G p.S2188C (on ENST00000297405 / NM_001363185.1; = p.S2084C on NM_052900.3) | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.676); catalogued as COSV52108195; called by muse, mutect2, varscan2
- CUL9 | c.5438C>T p.S1813L | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as rs1368531694, COSV52725650; called by muse, mutect2, varscan2
- DIP2C | c.559G>A p.G187R | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.079); catalogued as rs1263660136, COSV55146933; called by muse, mutect2, varscan2
- DSG1 | c.266G>C p.G89A | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57133385; called by muse, mutect2, varscan2
- EEA1 | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV59282857; called by muse, mutect2, varscan2
- ELMO1 | c.927G>A p.M309I | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.627); catalogued as COSV60296011; called by muse, mutect2, varscan2
- EXOC8 | c.2070G>C p.E690D | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV50477560; called by muse, mutect2, varscan2
- EXPH5 | c.1913G>A p.R638K | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV56199085, COSV56208272; called by muse, mutect2, varscan2
- F5 | c.2186G>C p.R729T | Missense Mutation (SNP) | VAF 37/233 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV63120938; called by muse, mutect2, varscan2
- FAM135B | c.2844G>T p.R948S | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV52706865; called by muse, mutect2, varscan2
- FAM83H | c.533A>G p.Y178C | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66353471; called by muse, mutect2, varscan2
- FRS3 | c.1232C>A p.P411H | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.525); catalogued as COSV52484007; called by muse, mutect2, varscan2
- FRZB | c.667C>G p.L223V | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.377); catalogued as COSV54552924; called by muse, mutect2, varscan2
- GLA | c.463G>C p.D155H | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs113419388, CM053274, COSV54508180; called by muse, mutect2, varscan2
- GRAMD2B | c.541C>A p.L181I | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53505943; called by muse, mutect2, varscan2
- GRHL1 | c.1537G>A p.D513N | Missense Mutation (SNP) | VAF 35/275 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as COSV61406527; called by muse, mutect2, varscan2
- HSPB2 | c.194C>A p.S65Y | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV57051278; called by muse, mutect2
- IGKV3-11 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.198); catalogued as rs1169212670; called by muse, mutect2, varscan2
- IL20RA | c.575G>A p.R192K | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (0.95); PolyPhen benign (0.012); catalogued as COSV57356471; called by muse, mutect2, varscan2
- ITGA2 | c.1910C>T p.S637F | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV56856629; called by muse, mutect2, varscan2
- JMJD1C | c.6085G>A p.E2029K | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as COSV59512958; called by muse, mutect2, varscan2
- KRT6C | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52877502; called by muse, mutect2, varscan2
- LARP4B | c.603G>T p.K201N | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.705); catalogued as COSV60220053; called by muse, mutect2, varscan2
- LRRC19 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as COSV66259330, COSV66259675; called by muse, mutect2, varscan2
- MAPK3 | c.545T>A p.I182N | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV53771184; called by muse, mutect2, varscan2
- MAT1A | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.125); catalogued as rs762357538, COSV64744731; called by muse, mutect2, varscan2
- MFSD10 | c.332C>G p.S111C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53266534, COSV53269719; called by muse, varscan2
- MTMR3 | c.848A>G p.N283S | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs138787389; called by muse, mutect2, varscan2
- MYO1F | c.517G>C p.E173Q | Missense Mutation (SNP) | VAF 10/169 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.777); catalogued as COSV100596593, COSV57792110; called by muse, mutect2
- MYOM3 | c.3793G>A p.D1265N | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.332); catalogued as rs895877283, COSV58390021; called by muse, mutect2, varscan2
- NELFE | c.727G>C p.E243Q | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.289); catalogued as COSV64810229; called by muse, mutect2, varscan2
- NELFE | c.460G>C p.E154Q | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.031); catalogued as COSV64810232; called by muse, mutect2, varscan2
- NOS1 | c.2237C>G p.S746W | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57607206; called by muse, mutect2, varscan2
- NT5DC1 | c.365-2A>G p.X122_splice | Splice Site (SNP) | VAF 8/31 reads (26%) | catalogued as COSV54572215; called by muse, varscan2
- NTHL1 | c.528C>G p.I176M (on ENST00000219066; = p.I168M on NM_002528.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54592320, COSV54594126; called by muse, mutect2
- OR14J1 | c.95C>T p.T32I | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65845523; called by muse, mutect2, varscan2
- PAN3 | c.1264C>T p.H422Y | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as COSV56701256; called by muse, mutect2, varscan2
- PCDH15 | c.4301C>T p.A1434V | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.085); catalogued as rs572629527, COSV57265897; called by muse, mutect2, varscan2
- PCDHGA9 | c.239G>T p.R80L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.612); catalogued as rs368387997, COSV53903438; called by muse, mutect2, varscan2
- PCDHGA9 | c.334G>C p.D112H | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.412); catalogued as COSV104389876, COSV53903451; called by muse, mutect2, varscan2
- PCNT | c.8131G>A p.E2711K | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs756579852, COSV64025307, COSV64027585; called by muse, mutect2, varscan2
- PHF20L1 | c.2216G>A p.R739H | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.425); catalogued as rs369386336; called by muse, mutect2, varscan2
- PHOSPHO2 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55865771; called by muse, mutect2, varscan2
- PLB1 | c.1473G>A p.M491I | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); catalogued as COSV59819701; called by muse, mutect2
- PLXND1 | c.3243C>G p.V1081= | Splice Region (SNP) | VAF 24/138 reads (17%) | catalogued as COSV60709653, COSV60720484; called by muse, varscan2
- PNLIP | c.1334+1G>A p.X445_splice | Splice Site (SNP) | VAF 24/105 reads (23%) | catalogued as COSV65039758; called by muse, mutect2, varscan2
- POLE | c.247G>C p.D83H | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV57674758; called by muse, mutect2, varscan2
- POLG2 | c.924T>G p.D308E | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV73346988; called by muse, mutect2
- PROS1 | c.1070G>T p.G357V | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM092263, COSV67777707; called by muse, mutect2
- PRR35 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as COSV99552160; called by muse, mutect2
- RALGAPB | c.3169G>C p.E1057Q | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.043); catalogued as COSV53434591; called by muse, mutect2, varscan2
- REC8 | c.1136G>A p.R379Q | Missense Mutation (SNP) | VAF 14/225 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs749657278, COSV61015230; called by muse, mutect2
- RHOBTB3 | c.1413del p.L472Cfs*4 | Frame Shift Del (DEL) | VAF 17/83 reads (20%) | catalogued as COSV66101188; called by mutect2, pindel, varscan2
- RPGR | c.1313C>G p.S438C | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.885); catalogued as COSV58832609; called by muse, mutect2, varscan2
- RTTN | c.2197C>G p.L733V | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776126193, COSV55341618; called by muse, mutect2, varscan2
- RXRA | c.80C>G p.S27C | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.494); catalogued as COSV62683580; called by muse, mutect2, varscan2
- SCN1A | c.5596G>T p.D1866Y (on ENST00000303395 / NM_001202435.3; = p.D1855Y on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121918815, CM045197, COSV57661006; ClinVar: not provided; called by muse, mutect2, varscan2
- SECISBP2L | c.2713G>A p.E905K (on ENST00000559471 / NM_001193489.2; = p.E860K on NM_014701.4) | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV55932817; called by muse, mutect2, varscan2
- SETD5 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100201300, COSV56707743; called by muse, mutect2, varscan2
- SF3B3 | c.242G>A p.G81D | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56785402; called by muse, mutect2, varscan2
- SF3B5 | c.137A>G p.H46R | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62451050; called by muse, mutect2, varscan2
- SGO2 | c.354G>C p.L118F | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63414011; called by muse, mutect2
- SIM1 | c.92C>T p.S31L | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as rs375766542, COSV53489181, COSV53493373; called by muse, mutect2, varscan2
- SLC25A1 | c.462G>C p.Q154H | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53205254; called by muse, mutect2, varscan2
- SLC26A4 | c.1149+1G>A p.X383_splice | Splice Site (SNP) | VAF 20/141 reads (14%) | catalogued as CS118060, COSV55914562; called by muse, mutect2, varscan2
- SLC4A11 | c.1062C>A p.F354L | Missense Mutation (SNP) | VAF 17/185 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV66260555, COSV66262025; called by muse, mutect2
- SMARCA2 | c.2812C>A p.L938I | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61804922; called by muse, mutect2, varscan2
- SOX5 | c.133G>T p.D45Y | Missense Mutation (SNP) | VAF 40/260 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.75); catalogued as COSV58619365; called by muse, mutect2, varscan2
- SUZ12 | c.1129C>T p.L377F | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1446094255, COSV100496747, COSV59498162; called by muse, mutect2, varscan2
- SYNM | c.1486C>G p.L496V | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.044); catalogued as COSV60374327; called by muse, mutect2
- TAPBP | c.1319G>A p.C440Y | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV70456638; called by muse, mutect2, varscan2
- TASOR2 | c.5029G>A p.E1677K | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.534); catalogued as COSV60165622; called by muse, mutect2, varscan2
- TELO2 | c.1790C>T p.S597L | Missense Mutation (SNP) | VAF 19/203 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as COSV51976095; called by muse, mutect2
- TGM4 | c.895G>C p.E299Q | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); catalogued as COSV56092816; called by muse, mutect2, varscan2
- TICRR | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51538204; called by muse, mutect2
- TRPM5 | c.3122G>A p.R1041K | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV50144906; called by muse, mutect2
- TTLL9 | c.1096C>A p.H366N | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs1305735001, COSV60589801; called by muse, mutect2, varscan2
- TUBA3D | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 20/275 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.964); catalogued as rs771034023, COSV58312601; called by muse, mutect2
- TUBA3E | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs1389134112; called by muse, mutect2, varscan2
- TXLNB | c.796G>C p.E266Q | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.831); catalogued as rs140293549; called by muse, mutect2, varscan2
- UGT1A1 | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 14/208 reads (7%) | catalogued as COSV100529745; called by muse, mutect2
- UGT3A2 | c.701G>C p.R234T | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV56928587; called by muse, mutect2, varscan2
- UQCRHL | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 16/213 reads (8%) | catalogued as COSV72331575; called by muse, mutect2
- USP15 | c.2887G>A p.E963K (on ENST00000280377 / NM_001351159.2; = p.E934K on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.332); catalogued as COSV54788152; called by muse, mutect2, varscan2
- USP26 | c.95G>T p.R32I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.372); catalogued as COSV63708104, COSV63709150; called by muse, mutect2
- VPS13A | c.7094C>T p.P2365L | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.406); catalogued as COSV62425505; called by muse, mutect2, varscan2
- VPS13D | c.8209C>G p.L2737V | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.062); catalogued as COSV50622809; called by muse, mutect2, varscan2
- VWA3B | c.727G>A p.V243M | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV68241036; called by muse, mutect2, varscan2
- WAPL | c.3200A>G p.D1067G | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as COSV53932548; called by muse, mutect2
- WDR45 | c.695G>T p.R232L (on ENST00000376372 / NM_001029896.2; = p.R233L on NM_007075.3) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59875449, COSV59875918; called by muse, mutect2, varscan2
- WDTC1 | c.1834G>C p.E612Q (on ENST00000319394 / NM_001276252.2; = p.E611Q on NM_015023.5) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.344); catalogued as COSV60087203; called by muse, mutect2, varscan2
- WNT7A | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 10/80 reads (13%) | catalogued as COSV53202152; called by muse, mutect2, varscan2
- YEATS2 | c.605C>T p.S202L | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.632); catalogued as COSV59361719; called by muse, mutect2
- ZC3H18 | c.2299G>C p.E767Q | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.98); catalogued as COSV56322751, COSV56324196; called by muse, mutect2, varscan2
- ZDHHC5 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.348); catalogued as COSV54705144, COSV54705852; called by muse, mutect2
- ZFP30 | c.1217G>A p.G406E | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63622355; called by muse, mutect2, varscan2
- ZIK1 | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.88); catalogued as rs766499307, COSV56736492; called by muse, mutect2, varscan2
- ZNF214 | c.455G>C p.R152T | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.193); catalogued as COSV53480743; called by muse, mutect2, varscan2
- ZNF233 | c.1597G>C p.E533Q | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV61933257; called by muse, mutect2
- ZNF521 | c.726G>A p.M242I | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as COSV64122787; called by muse, mutect2, varscan2
- ZNF660 | c.580G>C p.E194Q | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.839); catalogued as COSV59548545; called by muse, mutect2, varscan2
- ZNF75A | c.808G>C p.E270Q | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV73039569; called by muse, mutect2, varscan2
- ZNF781 | c.64C>G p.Q22E | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.436); catalogued as COSV62200428; called by muse, mutect2, varscan2
- CNTLN | c.4193A>T p.Y1398F | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.833); called by muse, mutect2
- DUSP6 | c.600dup p.N201Qfs*48 | Frame Shift Ins (INS) | VAF 17/144 reads (12%) | called by mutect2, pindel, varscan2
- ELAVL4 | c.260T>G p.L87* | Nonsense Mutation (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2
- FANCE | c.1003C>T p.Q335* | Nonsense Mutation (SNP) | VAF 48/216 reads (22%) | called by muse, mutect2, varscan2
- GIGYF2 | c.1124C>A p.S375* | Nonsense Mutation (SNP) | VAF 17/91 reads (19%) | called by muse, mutect2, varscan2
- ITGAM | c.3038C>A p.A1013D (on ENST00000648685 / NM_001145808.2; = p.A1012D on NM_000632.4) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2
- MAK | c.1007A>C p.Q336P | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.282); called by muse, mutect2
- SEC24A | c.1675C>T p.Q559* | Nonsense Mutation (SNP) | VAF 15/61 reads (25%) | called by muse, mutect2, varscan2
- SLC26A8 | c.2069C>G p.S690* | Nonsense Mutation (SNP) | VAF 4/72 reads (6%) | called by muse, mutect2
- SNX13 | c.1274G>A p.R425K | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TBC1D20 | c.499G>T p.E167* | Nonsense Mutation (SNP) | VAF 12/126 reads (10%) | called by muse, mutect2
- TTN | c.27496C>T p.Q9166* (on ENST00000591111; = p.Q8239* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 12/142 reads (8%) | called by muse, mutect2
- TTN | c.2371-1_2377del p.X791_splice (on ENST00000591111; = p.X745_splice on NM_003319.4) | Splice Site (DEL) | VAF 12/82 reads (15%) | called by mutect2, pindel, varscan2
- UBE2R2 | c.46G>C p.E16Q | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.779); called by muse, mutect2
- UGT3A2 | c.312-1G>A p.X104_splice | Splice Site (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2
- ADPRHL1 | c.972C>T p.L324= | Silent (SNP) | VAF 32/133 reads (24%) | catalogued as rs372483819, COSV62909835; called by muse, mutect2, varscan2
- ADRM1 | c.6G>A p.T2= | Silent (SNP) | VAF 11/144 reads (8%) | catalogued as rs751294764, COSV53385744; called by muse, mutect2
- AMIGO3 | c.888G>A p.L296= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs1466765082, COSV57537573; called by muse, mutect2, varscan2
- AMIGO3 | c.405G>A p.L135= | Silent (SNP) | VAF 22/120 reads (18%) | catalogued as COSV57537586; called by muse, varscan2
- ANO1 | c.1521G>A p.L507= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV60281370; called by muse, mutect2, varscan2
- ATAD2 | c.516G>T p.L172= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as COSV54877586; called by muse, mutect2, varscan2
- ATP1A1 | c.693C>T p.F231= | Silent (SNP) | VAF 6/75 reads (8%) | catalogued as rs1172639921, COSV55189711; called by muse, mutect2
- BRD1 | c.1770C>T p.P590= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as rs937338781, COSV53454959; called by muse, mutect2, varscan2
- CLUH | c.1317C>T p.F439= (on ENST00000435359; = p.F477= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs752806033, COSV70927854; called by muse, mutect2, varscan2
- DBR1 | c.459G>C p.V153= | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as COSV53429061; called by muse, mutect2, varscan2
- EPS8L2 | c.318C>T p.I106= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs760285785, COSV59346837, COSV59349545; called by muse, mutect2, varscan2
- FAT3 | c.12639C>T p.R4213= | Silent (SNP) | VAF 17/99 reads (17%) | catalogued as COSV53078901; called by muse, mutect2, varscan2
- FKBP15 | c.1215T>C p.T405= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as COSV53032118; called by muse, mutect2, varscan2
- FRY | c.2052G>A p.S684= | Silent (SNP) | VAF 37/96 reads (39%) | catalogued as rs780810276, COSV66565588, COSV66573131; called by muse, mutect2, varscan2
- GDF9 | c.423A>G p.L141= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs777079606, COSV51525827; called by muse, mutect2, varscan2
- GGTLC1 | c.444C>A p.G148= | Silent (SNP) | VAF 64/216 reads (30%) | catalogued as COSV53846323, COSV99601000; called by muse, mutect2, varscan2
- GRIP1 | c.2760G>A p.L920= (on ENST00000359742 / NM_001379345.1; = p.L868= on NM_021150.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 16/131 reads (12%) | catalogued as COSV54015865, COSV54034289; called by muse, mutect2, varscan2
- GUCA1A | c.432C>T p.D144= | Silent (SNP) | VAF 36/196 reads (18%) | catalogued as rs1263382505, COSV50003478; called by muse, mutect2, varscan2
- HCN1 | c.1551C>T p.H517= | Silent (SNP) | VAF 7/84 reads (8%) | catalogued as rs1007416378, COSV100302170, COSV57494940; ClinVar: likely benign; called by muse, mutect2
- KIR2DL4 | c.237G>A p.V79= (on ENST00000396284; = p.V40= on NM_001080770.2) | Silent (SNP) | VAF 20/130 reads (15%) | called by muse, varscan2
- KLF11 | c.1407G>A p.L469= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as COSV59940005; called by muse, mutect2, varscan2
- KRT2 | c.729C>T p.L243= | Silent (SNP) | VAF 57/260 reads (22%) | catalogued as rs776156546, COSV59009116, COSV59009136; called by muse, mutect2, varscan2
- MEFV | c.2103G>A p.A701= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as rs104895095, COSV54818684; ClinVar: benign / not provided; called by muse, mutect2, varscan2
- MYO1E | c.1506C>T p.F502= | Silent (SNP) | VAF 11/206 reads (5%) | catalogued as rs913508027, COSV55682755; called by muse, mutect2
- OLFML1 | c.1053C>T p.I351= | Silent (SNP) | VAF 11/99 reads (11%) | catalogued as COSV55074505; called by muse, mutect2, varscan2
- PCDHA2 | c.639G>T p.V213= | Silent (SNP) | VAF 26/105 reads (25%) | catalogued as COSV65364809; called by muse, mutect2, varscan2
- PCNT | c.7770G>A p.E2590= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV64025301; called by muse, mutect2, varscan2
- PCNT | c.8382G>A p.L2794= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV64025311; called by muse, mutect2, varscan2
- PGM1 | c.552C>T p.F184= | Silent (SNP) | VAF 8/112 reads (7%) | catalogued as COSV64300092; called by muse, mutect2
- RAB11FIP5 | c.1218G>C p.L406= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as COSV50247982; called by muse, mutect2, varscan2
- RALGAPB | c.3369G>A p.L1123= | Silent (SNP) | VAF 30/107 reads (28%) | catalogued as COSV53434604; called by muse, mutect2, varscan2
- RBPJL | c.309G>A p.V103= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as COSV59212767; called by muse, mutect2, varscan2
- RGS9 | c.642C>G p.V214= | Silent (SNP) | VAF 38/189 reads (20%) | catalogued as rs762646805, COSV52223233; ClinVar: likely benign; called by muse, mutect2, varscan2
- SEMA5B | c.222C>T p.L74= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs1185718216, COSV52091187; called by muse, mutect2, varscan2
- SHISA3 | c.498G>C p.T166= | Silent (SNP) | VAF 16/139 reads (12%) | catalogued as COSV59979478, COSV59979641; called by muse, mutect2, varscan2
- SLC25A47 | c.840C>G p.L280= | Silent (SNP) | VAF 32/133 reads (24%) | catalogued as rs1273623098, COSV59924451, COSV59925631; called by muse, mutect2, varscan2
- SLC4A11 | c.1269C>A p.L423= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV66260544; called by muse, mutect2, varscan2
- SLIT3 | c.3777A>G p.P1259= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as COSV60593751; called by muse, mutect2, varscan2
- SPTBN1 | c.5445G>A p.K1815= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV61685743; called by muse, mutect2, varscan2
- TAS2R1 | c.606G>A p.G202= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV66778180; called by muse, mutect2, varscan2
- TIAM1 | c.1551C>T p.L517= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV54538628; called by muse, mutect2, varscan2
- TMEM104 | c.72C>T p.L24= | Silent (SNP) | VAF 24/266 reads (9%) | catalogued as COSV59108014; called by muse, mutect2
- TNXB | c.10959G>A p.R3653= (on ENST00000647633; = p.R3406= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV64474006; called by muse, mutect2, varscan2
- TP73 | c.702G>A p.Q234= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV60698653; called by muse, mutect2, varscan2
- USP15 | c.1524A>G p.A508= (on ENST00000280377 / NM_001351159.2; = p.A479= on NM_006313.3 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV54788119; called by muse, mutect2, varscan2
- USP28 | c.1857C>T p.I619= | Silent (SNP) | VAF 10/94 reads (11%) | catalogued as COSV50155920; called by muse, mutect2, varscan2
- VWCE | c.2784C>G p.L928= | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as COSV57111051, COSV57115662; called by muse, mutect2, varscan2
- WDTC1 | c.999C>T p.S333= (on ENST00000319394 / NM_001276252.2; = p.S332= on NM_015023.5) | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs371464043; called by muse, mutect2, varscan2
- ZFPL1 | c.828C>T p.F276= | Silent (SNP) | VAF 7/121 reads (6%) | called by muse, mutect2
- B4GALNT1 | c.*2866G>A | 3'UTR (SNP) | VAF 15/118 reads (13%) | catalogued as COSV57541386; called by muse, mutect2, varscan2
- CDKL1 | c.171+17378C>T | Intron (SNP) | VAF 14/40 reads (35%) | catalogued as rs1566604487; called by muse, mutect2, varscan2
- IGKV1-13 | n.136C>T | RNA (SNP) | VAF 28/149 reads (19%) | catalogued as rs1253761260; called by muse, mutect2, varscan2
- IL21R | c.*2G>A | 3'UTR (SNP) | VAF 13/41 reads (32%) | catalogued as COSV100559867; called by muse, mutect2, varscan2
- MAST4 | c.674+63803G>C | Intron (SNP) | VAF 22/89 reads (25%) | catalogued as COSV67789104; called by muse, mutect2, varscan2
- P4HA1 | c.1148+1053G>A | Intron (SNP) | VAF 34/296 reads (11%) | catalogued as rs980268214, COSV54958799; called by muse, mutect2, varscan2
- TBC1D12 | c.-2dup | 5'UTR (INS) | VAF 6/36 reads (17%) | called by mutect2, pindel, varscan2
- Unknown | chr21:16071211 C>G | IGR (SNP) | VAF 34/122 reads (28%) | catalogued as rs1440166557; called by muse, varscan2
